Somatic mutation profile of tumor specimen MMRF_1897_1_PB_CD138pos (aliquot MMRF_1897_1_PB_CD138pos_T1_KBS5U_L05811) from MMRF case MMRF_1897, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,041 days).
Specimen MMRF_1897_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ebf3775-7de4-4027-ac21-81269c5cf124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1897_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1897_1_PB_CD3pos_C5_KBS5U_L05816; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a85c8c4-77c1-4a1b-a37a-f976d7fc3277

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | catalogued as rs1234606471; called by pindel, varscan2
- CCDC110 | c.115+263A>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- OTUD6A | c.*614G>A | 3'UTR (SNP) | VAF 3/18 reads (17%) | catalogued as rs1056968618; called by muse, mutect2
- RBPJ | c.*614C>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
